Gene-level copy-number profile of tumor specimen ALCH-AEQZ-TTP1-A from ALCHEMIST case ALCH-AEQZ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 57.3 years (20,924 days).
Specimen ALCH-AEQZ-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a02f7798-d5a3-4c22-aadc-7403618842a1.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AEQZ-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,742 have no estimate.
https://portal.gdc.cancer.gov/files/6b5dfda4-6000-47c8-8111-4e79a7a689d1

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 93; copy number 1: 7,471; copy number 2: 46,667; copy number 3: 4,473; copy number 4: 105; copy number 5: 27; copy number 6: 7; copy number 7: 11; copy number 8: 9; copy number 9: 2; copy number 10: 3; copy number 11: 1; copy number 12: 3; copy number 15: 4; copy number 16: 1; copy number 20: 4.

Homozygous deletions (total copy number 0; autosomes only): 93 genes in 39 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,216,909–1,235,041, 2 genes: SDF4, B3GALT6.
- chr1:1,275,223–1,280,420, 1 gene: LINC01786.
- chr1:4,654,609–4,792,534, 2 genes: AJAP1, Z98886.1.
- chr1:12,892,896–12,898,270, 1 gene (within-gene range 0–1): PRAMEF10.
- chr2:2,729,908–2,730,957, 1 gene: AC018685.1.
- chr2:45,005,182–45,013,668, 2 genes: SIX2, AC093702.1.
- chr2:89,252,211–89,310,144, 8 genes: IGKV3-31, IGKV1-32, IGKV1-33, IGKV3-34, IGKV1-35, IGKV2-36, IGKV1-37, IGKV2-38.
- chr2:91,686,102–91,723,605, 2 genes: AC027612.2, NKAIN1P2.
- chr2:236,072,295–236,168,386, 2 genes (within-gene range 0–2): RN7SL204P, GBX2.
- chr4:188,159,705–188,161,157, 1 gene: LINC02434.
- chr5:181,291,673–181,342,213, 5 genes: AC008443.5, RNU6-705P, AC138035.1, AC138035.3, AC138035.2.
- chr6:149,977,471–150,005,157, 3 genes: AL355497.1, BTF3P10, RAET1K.
- chr6:150,061,053–150,069,121, 1 gene: ULBP3.
- chr8:143,706,694–143,708,109, 1 gene (within-gene range 0–1): CCDC166.
- chr9:61,665,579–61,666,386, 1 gene: AL935212.2.
- chr9:63,703,065–63,720,441, 2 genes: AL591438.2, CDRT15P7.
- chr9:136,975,092–136,986,410, 3 genes (within-gene range 0–9): PTGDS, AL807752.7, LCNL1.
- chr10:30,723,251–30,723,740, 1 gene: LINC02644.
- chr11:65,525,077–65,538,704, 1 gene (within-gene range 0–2): SCYL1.
- chr11:70,705,167–70,706,068, 2 genes (within-gene range 0–1): Y_RNA, AP000590.1.
- chr11:71,473,503–71,473,568, 1 gene (within-gene range 0–1): MIR6754.
- chr14:18,333,726–18,343,144, 2 genes: CR383658.1, RNU6-458P.
- chr14:18,418,775–18,419,273, 1 gene: BNIP3P6.
- chr14:18,601,045–18,602,129, 1 gene: OR11H12.
- chr14:18,667,249–18,712,643, 5 genes: CR383656.3, RPL22P20, CR383656.4, CR383656.2, NF1P10.
- chr14:19,124,807–19,337,730, 13 genes: AL589743.3, NBEAP5, AL589182.2, OR11H13P, AL589743.2, AL589743.4, CDRT15P13, NBEAP6, AL589743.1, TOMM40P1, DUXAP10, BMS1P17, AL929602.1.
- chr14:105,536,861–105,537,239, 1 gene: ATP5MC1P1.
- chr14:106,850,885–106,851,417, 2 genes: MIR5195, IGHV5-78.
- chr16:1,148,224–1,148,754, 1 gene: AC120498.8.
- chr16:32,475,051–32,478,250, 1 gene: ABCD1P3.
- chr17:142,789–191,587, 2 genes: DOC2B, LINC02091.
- chr17:22,090,743–22,221,605, 2 genes: UBBP4, FTLP13.
- chr17:22,266,395–22,288,301, 2 genes: AC138761.1, AC138761.2.
- chr17:22,331,597–22,332,410, 1 gene: AC087575.1.
- chr19:1,086,574–1,095,380, 1 gene (within-gene range 0–2): POLR2E.
- chr20:24,679,547–24,680,991, 1 gene: AL049594.1.
- chr21:13,038,160–13,120,807, 4 genes: ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1.
- chr22:18,150,170–18,177,397, 1 gene: USP18.
- chr22:18,400,407–18,577,968, 9 genes: PPP1R26P3, FAM230A, AC023490.2, FAM247B, GGTLC3, Metazoa_SRP, AC023490.3, TMEM191B, PI4KAP1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 72 genes in 29 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,173,056–1,179,555, 1 gene, copy number 5 (within-gene range 1–5): TTLL10-AS1.
- chr1:1,203,508–1,214,153, 2 genes, copy number 5: TNFRSF18, TNFRSF4.
- chr1:1,242,446–1,251,334, 2 genes, copy number 8–9: C1QTNF12, AL162741.1.
- chr1:1,280,436–1,309,609, 3 genes, copy number 7–10 (within-gene range 4–10): SCNN1D, ACAP3, MIR6726.
- chr1:1,615,415–1,630,610, 1 gene, copy number 7 (within-gene range 2–7): MIB2.
- chr6:31,394,289–31,415,315, 2 genes, copy number 5 (within-gene range 3–5): AL645933.2, MICA.
- chr6:31,402,152–31,402,250, 1 gene, copy number 5 (within-gene range 3–5): Y_RNA.
- chr6:37,212,178–37,258,155, 2 genes, copy number 5 (within-gene range 3–5): TMEM217, AL353579.1.
- chr8:143,573,490–143,583,304, 4 genes, copy number 6 (within-gene range 3–6): AC067930.4, NAPRT, AC067930.5, AC067930.1.
- chr8:143,612,618–143,618,048, 1 gene, copy number 8: GFUS.
- chr8:143,790,920–143,815,773, 2 genes, copy number 5 (within-gene range 5–11): SCRIB, MIR937.
- chr8:143,833,270–143,840,256, 2 genes, copy number 7: AC234917.1, AC234917.2.
- chr8:143,977,153–144,051,522, 4 genes, copy number 5 (within-gene range 3–5): PARP10, GRINA, SPATC1, SMPD5.
- chr8:144,082,590–144,086,216, 1 gene, copy number 6: GPAA1.
- chr9:61,581,813–61,662,690, 4 genes, copy number 20: AL935212.3, FAM242D, Y_RNA, AL935212.1.
- chr9:136,546,173–136,549,893, 2 genes, copy number 7: MIR4674, NALT1.
- chr9:136,726,104–136,726,239, 2 genes, copy number 5: SNORA17B, SNORA17B.
- chr9:136,744,017–136,748,525, 2 genes, copy number 6 (within-gene range 4–6): LCN6, MIR6722.
- chr9:137,007,234–137,037,957, 3 genes, copy number 12 (within-gene range 1–12): ABCA2, C9orf139, FUT7.
- chr9:137,048,107–137,054,061, 2 genes, copy number 5–15: ENTPD2, AL807752.4.
- chr14:18,967,434–19,055,551, 5 genes, copy number 7–15: POTEM, AL929601.3, RNU6-1239P, AL589182.1, GRAMD4P4.
- chr14:105,472,962–105,499,575, 4 genes, copy number 8: CRIP2, CRIP1, AL928654.3, TEDC1.
- chr14:105,583,731–105,626,066, 3 genes, copy number 10–16 (within-gene range 2–16): IGHA2, IGHE, IGHG4.
- chr16:788,046–800,737, 2 genes, copy number 7 (within-gene range 2–7): CHTF18, GNG13.
- chr16:1,088,226–1,096,244, 1 gene, copy number 11: C1QTNF8.
- chr19:1,177,558–1,279,244, 9 genes, copy number 5: STK11, HMGB2P1, CBARP, AC004221.1, ATP5F1D, MIDN, CIRBP, CIRBP-AS1, FAM174C.
- chr19:1,852,382–1,863,579, 3 genes, copy number 8: AC012615.3, KLF16, AC012615.4.
- chr19:2,037,465–2,051,244, 1 gene, copy number 9: MKNK2.
- chr21:8,603,547–8,603,984, 1 gene, copy number 5: RPSAP68.

Autosomal genes at a single copy (total copy number 1): 4,615. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
